Somatic mutation profile of tumor specimen MMRF_2220_1_BM_CD138pos (aliquot MMRF_2220_1_BM_CD138pos_T1_KHS5U_L11060) from MMRF case MMRF_2220, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.9 years (20,784 days).
Specimen MMRF_2220_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f11ea49-dde7-446d-bd10-8cb8857b7f35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2220_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2220_1_PB_Whole_C2_KHS5U_L08783; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70932587-8f4e-47c8-a3f1-fd03cd8eaa73

The open-access MAF lists 139 somatic variants for this specimen: 64 protein-altering or splice-affecting, 14 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 28, Intron 22, Silent 14, 5'UTR 5, Nonsense Mutation 3, Splice Region 3, 3'Flank 3, Splice Site 2, RNA 2, Translation Start Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs761759820, COSV52209979; called by muse, mutect2, varscan2
- CHST15 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1218567186; called by muse, mutect2, varscan2
- CORO1A | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs771057764; called by muse, mutect2, varscan2
- DEPTOR | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 109/388 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs775505421; called by muse, mutect2, varscan2
- DUSP2 | c.730+1G>A p.X244_splice | Splice Site (SNP) | VAF 159/315 reads (50%) | catalogued as rs1405109165; called by muse, mutect2, varscan2
- DUSP2 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1261249430; called by muse, mutect2, varscan2
- GPR1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.04); catalogued as COSV67976973; called by muse, mutect2, varscan2
- IGHV1-69 | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs11557972; called by muse, mutect2, varscan2
- IGHV2-70 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 94/136 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370286145; called by muse, varscan2
- IGHV3-72 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 163/326 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs758698602, COSV70409465, COSV70409792; called by muse, mutect2, varscan2
- IGLL5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 48/50 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs550261872, COSV73249147; called by muse, mutect2, varscan2
- IGLON5 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs753948923; called by muse, mutect2, varscan2
- IGLV2-23 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 69/106 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs376640879; called by muse, mutect2, varscan2
- IGLV3-1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as rs61731687; called by muse, varscan2
- IGLV3-21 | c.281G>C p.S94T | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as rs369416480; called by muse, mutect2
- IL21R | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as rs267604484; called by muse, mutect2, varscan2
- LAMB4 | c.3547G>A p.D1183N | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV52713853; called by muse, mutect2
- MAP2K1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as COSV61071261; called by muse, mutect2, varscan2
- MBOAT7 | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs761264534; called by muse, mutect2
- MMP27 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV52779767; called by muse, mutect2
- PACRG | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61324292; called by muse, mutect2, varscan2
- PCDH15 | c.5035G>T p.G1679W (on ENST00000644397 / NM_001354429.2; = p.G1621W on NM_001142771.2) | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.765); catalogued as rs746744883; called by muse, mutect2, varscan2
- PIEZO1 | c.2245_2253del p.Q749_E751del | In Frame Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs762099096; called by mutect2, pindel
- PIK3C2G | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV56805494; called by muse, mutect2, varscan2
- PRAG1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373932683; called by muse, mutect2, varscan2
- SMTN | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as rs375442203; called by muse, mutect2, varscan2
- SULT1A1 | c.274+8_274+11del | Splice Region (DEL) | VAF 32/200 reads (16%) | catalogued as rs1334268935; called by mutect2, pindel
- USP49 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs200523441, COSV51900538; called by muse, mutect2, varscan2
- ZNF280C | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63969795; called by muse, mutect2, varscan2
- ATG4A | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATP11C | c.2372G>T p.C791F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1A | c.1613T>C p.V538A | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- CHL1 | c.2737G>A p.E913K (on ENST00000397491 / NM_001253387.1; = p.E929K on NM_006614.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL3A1 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DOCK1 | c.172-1G>A p.X58_splice | Splice Site (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- FZD7 | c.1531T>C p.Y511H | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- IGHV1-69D | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by mutect2, varscan2
- IGLV3-25 | c.281G>C p.S94T | Missense Mutation (SNP) | VAF 163/265 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGLV4-69 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL12A | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 125/250 reads (50%) | called by muse, mutect2, varscan2
- KCNU1 | c.1755A>C p.L585F | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MBIP | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MN1 | c.912_913insAAGCAG p.Q304_Q305insKQ | In Frame Ins (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel
- NXF1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.369); called by muse, mutect2
- PDK1 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- PITPNM3 | c.767T>A p.F256Y | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- POLD4 | c.19A>C p.I7L | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- POM121L12 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PROM1 | c.457T>G p.F153V | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- SF3B1 | c.2814G>C p.W938C | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SGO1 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC5A6 | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- SNCAIP | c.215A>T p.K72M | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX5 | c.1301C>G p.P434R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SRRT | c.249C>T p.D83= | Splice Region (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- SYNRG | c.1373del p.F458Sfs*42 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- TANC2 | c.5024A>C p.Q1675P | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBL1XR1 | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.926-4G>C | Splice Region (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2
- UQCRHL | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY3 | c.6869G>A p.R2290K | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- XPO5 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); called by muse, mutect2
- ZNF112 | c.190G>T p.E64* (on ENST00000337401 / NM_001083335.2; = p.E58* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 70/128 reads (55%) | called by muse, mutect2, varscan2
- ZW10 | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ADGRD1 | c.555C>T p.N185= | Silent (SNP) | VAF 26/399 reads (7%) | catalogued as rs530604865; called by muse, mutect2
- C14orf180 | c.411C>T p.A137= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- CFAP251 | c.1071C>T p.D357= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs772834701; called by muse, mutect2, varscan2
- CFAP65 | c.1638C>T p.L546= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs757444460; called by muse, mutect2
- CPNE3 | c.39T>G p.V13= | Silent (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- EFNB1 | c.591T>C p.G197= | Silent (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
- IGLV8-61 | c.129A>C p.T43= | Silent (SNP) | VAF 113/242 reads (47%) | catalogued as rs564976337; called by muse, mutect2, varscan2
- IRF2BP1 | c.1503G>A p.L501= | Silent (SNP) | VAF 76/155 reads (49%) | called by muse, mutect2, varscan2
- LRP3 | c.603G>A p.S201= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- PLSCR1 | c.318T>C p.D106= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- RIN2 | c.1686G>A p.R562= (on ENST00000255006 / NM_001242581.1; = p.R513= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/124 reads (34%) | called by muse, mutect2, varscan2
- SBF2 | c.4983G>A p.Q1661= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as rs777944204; called by muse, mutect2, varscan2
- SYTL5 | c.12C>T p.N4= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- TAF1 | c.2955A>G p.Q985= (on ENST00000373790 / NM_138923.4; = p.Q1006= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 155/314 reads (49%) | called by muse, mutect2, varscan2
- AC083864.1 | n.577G>A | RNA (SNP) | VAF 45/77 reads (58%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.*1626T>A | 3'UTR (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- ANKZF1 | c.-31+76G>T | Intron (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2
- ARHGAP26 | c.154+1851T>G | Intron (SNP) | VAF 30/443 reads (7%) | called by muse, mutect2
- CAPRIN1 | c.1294-77G>A | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as rs190845933; called by muse, mutect2
- CDH8 | c.1024-154T>G | Intron (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- CREB3L2 | c.583+163A>G | Intron (SNP) | VAF 151/317 reads (48%) | called by muse, mutect2, varscan2
- DISC1 | c.2307+432T>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1231-33G>T | Intron (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- DOCK1 | c.1059-51C>T | Intron (SNP) | VAF 23/47 reads (49%) | catalogued as rs374485488; called by muse, mutect2, varscan2
- EDC4 | c.-106T>G | 5'UTR (SNP) | VAF 29/73 reads (40%) | catalogued as rs1452361085; called by muse, mutect2, varscan2
- EYA4 | chr6:133531318 T>C | 3'Flank (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- FAM204A | chr10:118309804 T>A | 3'Flank (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- FAM204A | chr10:118309805 A>C | 3'Flank (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- GABRG1 | c.*1280T>G | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- GADL1 | c.1250+1622A>T | Intron (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- GJD2 | c.*1037G>A | 3'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, varscan2
- GOLGA4 | c.*426G>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- GRIA2 | c.-7C>A | 5'UTR (SNP) | VAF 152/316 reads (48%) | called by muse, mutect2, varscan2
- GTPBP10 | c.*2851T>C | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- HDAC4 | c.*2786T>C | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by mutect2, varscan2
- HS1BP3 | c.623+3694A>T | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- HSPB1 | c.*41T>G | 3'UTR (SNP) | VAF 64/136 reads (47%) | catalogued as rs902697493; called by muse, mutect2, varscan2
- IGLL5 | c.-194C>T | 5'UTR (SNP) | VAF 39/42 reads (93%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.-66A>C | 5'UTR (SNP) | VAF 104/148 reads (70%) | called by muse, mutect2, varscan2
- IGSF3 | c.*455C>A | 3'UTR (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- IKBKB | c.2205+46T>A | Intron (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- IL32 | c.253-47G>A | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as rs748819339; called by muse, mutect2, varscan2
- IYD | chr6:150368989 C>T | 5'Flank (SNP) | VAF 104/220 reads (47%) | catalogued as COSV57599979, COSV57601687; called by muse, mutect2, varscan2
- KCNK2 | c.*886A>G | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- KIAA0408 | c.*1766C>A | 3'UTR (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- LTB | c.163-18G>A | Intron (SNP) | VAF 268/553 reads (48%) | catalogued as rs758699441; called by muse, mutect2, varscan2
- MAPK8IP2 | c.*674G>A | 3'UTR (SNP) | VAF 48/92 reads (52%) | catalogued as rs920549513; called by muse, mutect2, varscan2
- MIR4527 | n.4G>A | RNA (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- MSH5 | c.415+36T>A | Intron (SNP) | VAF 16/544 reads (3%) | called by muse, mutect2
- MYSM1 | c.*909T>C | 3'UTR (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- NAALADL2 | c.*216A>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- NEIL1 | c.*1066C>G | 3'UTR (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- NTRK3 | c.*12207A>C | 3'UTR (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- OLFM4 | c.*233G>A | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- OTUB2 | c.*1643G>A | 3'UTR (SNP) | VAF 25/50 reads (50%) | catalogued as rs1484490510; called by muse, mutect2, varscan2
- PABPC5 | c.*1578_*1609del | 3'UTR (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel
- PLCB4 | c.*769T>C | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- PTGER3 | c.*485G>A | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- PTGER3 | c.*394G>T | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- S1PR2 | c.-43+784C>G | Intron (SNP) | VAF 38/79 reads (48%) | catalogued as rs538224926, COSV73912640, COSV73912837; called by muse, mutect2, varscan2
- SEPTIN14 | c.*843C>T | 3'UTR (SNP) | VAF 103/210 reads (49%) | called by muse, mutect2, varscan2
- SGO1 | c.1564+1011C>T | Intron (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.*1129C>T | 3'UTR (SNP) | VAF 66/128 reads (52%) | catalogued as rs778618067; called by muse, mutect2, varscan2
- SNX3 | c.-68G>A | 5'UTR (SNP) | VAF 5/54 reads (9%) | catalogued as COSV57778029; called by muse, mutect2
- SPINK1 | c.194+257del | Intron (DEL) | VAF 43/98 reads (44%) | called by mutect2, pindel, varscan2
- STEAP2 | c.*3497G>T | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- TMEM169 | c.*429T>C | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- TUSC3 | c.*79C>T | 3'UTR (SNP) | VAF 87/207 reads (42%) | called by muse, mutect2, varscan2
- TXNDC15 | c.*1828T>A | 3'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- UBE2D3 | c.198+160C>T | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- UBR4 | c.15488-50G>A | Intron (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
- VOPP1 | c.*1655C>G | 3'UTR (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- VPS26B | c.381-11G>A | Intron (SNP) | VAF 15/45 reads (33%) | catalogued as rs375988523; called by muse, mutect2, varscan2
- ZCCHC17 | c.318-9T>G | Intron (SNP) | VAF 35/55 reads (64%) | called by muse, mutect2, varscan2
- ZNF211 | c.90+336A>C | Intron (SNP) | VAF 7/185 reads (4%) | called by muse, mutect2
